Somatic mutation profile of cancer-model specimen HCM-CSHL-0159-C18-85B (3D Organoid; aliquot HCM-CSHL-0159-C18-85B-01D-A786-36), derived from the primary tumor of HCMI case HCM-CSHL-0159-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Tumor grade: GB; Age at diagnosis: 61.9 years (22,623 days).
Specimen HCM-CSHL-0159-C18-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ffc464b-21c5-4f16-b6ce-0c7073cdb1ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0159-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0159-C18-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65d818cc-0ed3-4671-837b-3036679758a1

The open-access MAF lists 168 somatic variants for this specimen: 112 protein-altering or splice-affecting, 44 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 44, Intron 8, Splice Site 6, Nonsense Mutation 5, Frame Shift Del 3, 3'UTR 2, Splice Region 1, RNA 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 63/160 reads (39%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 342/541 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACOT9 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs770414891; called by muse, mutect2
- ACSM5 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 221/657 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750548939, COSV59371010; called by muse, mutect2, varscan2
- ADAMTSL1 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 146/281 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780536559, COSV52810410; called by muse, mutect2, varscan2
- ADCK5 | c.1226A>C p.D409A | Missense Mutation (SNP) | VAF 157/178 reads (88%) | SIFT tolerated (0.17); PolyPhen benign (0.381); catalogued as rs782208902, COSV58233174; called by muse, mutect2, varscan2
- ADRA1A | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 557/631 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs759868914; called by muse, mutect2, varscan2
- ANO4 | c.2584C>T p.R862C (on ENST00000392977 / NM_001286615.2; = p.R827C on NM_178826.4) | Missense Mutation (SNP) | VAF 18/560 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774274653, COSV54595545; called by muse, mutect2
- APC | c.3750del p.V1251Ffs*14 | Frame Shift Del (DEL) | VAF 56/150 reads (37%) | catalogued as CM106370; called by mutect2, pindel, varscan2
- AURKA | c.222G>C p.Q74H | Missense Mutation (SNP) | VAF 226/1051 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs769911074; called by muse, mutect2, varscan2
- BRD1 | c.3043A>G p.I1015V (on ENST00000216267 / NM_001349940.1; = p.I1146V on NM_001304808.3) | Missense Mutation (SNP) | VAF 146/293 reads (50%) | SIFT tolerated (0.87); PolyPhen benign (0.358); catalogued as rs769189277; called by muse, mutect2, varscan2
- BRSK1 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 108/262 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1271951177, COSV58665422; called by muse, mutect2, varscan2
- CAPN6 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 453/453 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759834539, COSV60695723; called by muse, mutect2, varscan2
- CEP290 | c.6417dup p.V2140Sfs*3 | Frame Shift Ins (INS) | VAF 79/308 reads (26%) | catalogued as rs1225676118; called by mutect2, pindel, varscan2
- COL1A2 | c.3794C>T p.S1265F | Missense Mutation (SNP) | VAF 210/344 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99798941; called by muse, mutect2, varscan2
- COL4A4 | c.2629C>T p.R877W | Missense Mutation (SNP) | VAF 270/833 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs55948916; called by muse, mutect2, varscan2
- CROCC | c.196+1G>A p.X66_splice | Splice Site (SNP) | VAF 18/180 reads (10%) | catalogued as rs766102968, COSV65009969; called by muse, mutect2
- CSMD3 | c.8029G>T p.D2677Y (on ENST00000297405 / NM_001363185.1; = p.D2573Y on NM_052900.3) | Missense Mutation (SNP) | VAF 64/638 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52160940; called by muse, mutect2, varscan2
- CTNNB1 | c.1525-1G>A p.X509_splice | Splice Site (SNP) | VAF 56/700 reads (8%) | catalogued as COSV100846333; called by muse, mutect2
- DHX35 | c.1157C>G p.S386* | Nonsense Mutation (SNP) | VAF 158/835 reads (19%) | catalogued as COSV52669444; called by muse, mutect2, varscan2
- DNAH8 | c.1649T>C p.V550A | Missense Mutation (SNP) | VAF 35/342 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.123); catalogued as rs571479487; called by muse, mutect2, varscan2
- DSCAML1 | c.5961G>C p.E1987D (on ENST00000321322; = p.E1927D on NM_020693.4) | Missense Mutation (SNP) | VAF 308/732 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.332); catalogued as COSV58382539; called by muse, mutect2, varscan2
- DSCAML1 | c.4858G>A p.G1620S (on ENST00000321322; = p.G1560S on NM_020693.4) | Missense Mutation (SNP) | VAF 130/289 reads (45%) | SIFT tolerated (0.39); PolyPhen probably damaging (1); catalogued as rs756292633; called by muse, mutect2, varscan2
- GALNT17 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1212228242, COSV100352632; called by muse, mutect2, varscan2
- GLI3 | c.4610G>A p.R1537H | Missense Mutation (SNP) | VAF 215/326 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs746798261, COSV67886970; called by muse, mutect2, varscan2
- H3C2 | c.18G>C p.Q6H | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1278314228, COSV52517760; called by muse, mutect2
- HOXA6 | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 158/487 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56074403; called by muse, mutect2, varscan2
- HYDIN | c.6715C>G p.L2239V | Missense Mutation (SNP) | VAF 66/117 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs763638148; called by muse, mutect2, varscan2
- IGFBP6 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 188/281 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs201732293; called by muse, mutect2, varscan2
- ITGA9 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 290/585 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1238331400; called by muse, mutect2, varscan2
- IZUMO3 | c.452G>C p.R151P (on ENST00000543880 / NM_001365008.2; = p.R145P on NM_001271706.1) | Missense Mutation (SNP) | VAF 108/283 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs766196413, COSV101371484; called by muse, mutect2, varscan2
- KANSL1L | c.1261C>G p.P421A | Missense Mutation (SNP) | VAF 22/369 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1467394899; called by muse, mutect2
- KCNN1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 105/228 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs759749668; called by muse, mutect2, varscan2
- LRRC18 | c.402C>A p.D134E | Missense Mutation (SNP) | VAF 89/188 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as rs748369916; called by muse, mutect2, varscan2
- MAGEE2 | c.1126C>A p.H376N | Missense Mutation (SNP) | VAF 292/292 reads (100%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.816); catalogued as rs1232336885; called by muse, mutect2, varscan2
- MDGA2 | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 144/197 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV62108048; called by muse, mutect2, varscan2
- MYCBP2 | c.468C>G p.I156M (on ENST00000357337; = p.I194M on NM_015057.5) | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as COSV62020426; called by muse, mutect2
- MYF5 | c.271C>G p.R91G | Missense Mutation (SNP) | VAF 254/1107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57356108; called by muse, mutect2, varscan2
- N4BP3 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 139/302 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs751253637, COSV51062277; called by muse, mutect2, varscan2
- N4BP3 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 194/390 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs777656725, COSV51066818; called by muse, mutect2, varscan2
- PCDHA7 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 124/259 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.195); catalogued as rs782197887, COSV65337155; called by muse, mutect2, varscan2
- PCDHB15 | c.2220C>A p.S740R | Missense Mutation (SNP) | VAF 245/537 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.07); catalogued as COSV99179305; called by muse, mutect2, varscan2
- PP2D1 | c.1445G>A p.C482Y | Missense Mutation (SNP) | VAF 93/179 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750617391; called by muse, mutect2, varscan2
- PRB2 | c.245C>G p.P82R | Missense Mutation (SNP) | VAF 79/472 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.048); catalogued as rs1380862911; called by muse, varscan2
- PTPRR | c.1159G>A p.V387M | Missense Mutation (SNP) | VAF 235/346 reads (68%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs144918296; called by muse, mutect2, varscan2
- RAPH1 | c.1-1G>C p.X1_splice | Splice Site (SNP) | VAF 85/248 reads (34%) | catalogued as COSV57356059; called by muse, mutect2, varscan2
- RFX4 | c.760G>A p.V254M (on ENST00000392842 / NM_213594.3; = p.V160M on NM_032491.6) | Missense Mutation (SNP) | VAF 197/684 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs759576190, COSV99986103; called by muse, mutect2, varscan2
- SFMBT1 | c.2066C>T p.T689I | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV56254323, COSV56254519; called by muse, mutect2
- STON1-GTF2A1L | c.2962C>T p.H988Y | Missense Mutation (SNP) | VAF 89/485 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV59135682; called by muse, mutect2, varscan2
- USP28 | c.2357G>A p.R786H | Missense Mutation (SNP) | VAF 74/151 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs550263885, COSV50155875; called by muse, mutect2, varscan2
- UST | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as rs772986508, COSV66546029; called by muse, mutect2, varscan2
- VAT1L | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 208/588 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.528); catalogued as rs748130621; called by muse, mutect2, varscan2
- VPS13B | c.11008G>A p.G3670R | Missense Mutation (SNP) | VAF 801/914 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61754108, COSV62156409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR33 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 129/375 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100459383; called by muse, mutect2, varscan2
- ZFHX4 | c.7015G>T p.E2339* | Nonsense Mutation (SNP) | VAF 222/460 reads (48%) | catalogued as COSV50838972; called by muse, mutect2, varscan2
- ADGRG4 | c.913A>G p.T305A | Missense Mutation (SNP) | VAF 165/165 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- AKAP6 | c.4318G>T p.V1440F | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ARHGAP22 | c.497A>G p.K166R | Missense Mutation (SNP) | VAF 202/444 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ATG9A | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BANK1 | c.1903T>C p.F635L | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BSN | c.6317A>C p.N2106T | Missense Mutation (SNP) | VAF 143/257 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C7orf57 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 284/440 reads (65%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CA1 | c.535A>T p.N179Y | Missense Mutation (SNP) | VAF 37/768 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CAPZA3 | c.284A>G p.D95G | Missense Mutation (SNP) | VAF 106/330 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- CHD4 | c.1444-17_1444-2delinsAG p.X482_splice (on ENST00000357008 / NM_001363606.2; = p.X495_splice on NM_001273.5) | Splice Site (DEL) | VAF 28/55 reads (51%) | called by pindel, varscan2*
- CNTRL | c.2425G>T p.V809L | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL28A1 | c.1390G>A p.G464S | Missense Mutation (SNP) | VAF 9/285 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CPS1 | c.4274+1G>T p.X1425_splice | Splice Site (SNP) | VAF 36/680 reads (5%) | called by muse, mutect2
- CRMP1 | c.38C>T p.T13M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DNAH10 | c.10024G>T p.E3342* (on ENST00000409039; = p.E3281* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 308/487 reads (63%) | called by muse, mutect2, varscan2
- DNAH9 | c.10606A>C p.I3536L | Missense Mutation (SNP) | VAF 206/327 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- DNER | c.2073C>A p.S691R | Missense Mutation (SNP) | VAF 281/446 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DRAM1 | c.197T>A p.L66H | Missense Mutation (SNP) | VAF 199/305 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DSTYK | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 403/886 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EDRF1 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 126/252 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- EML6 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 266/407 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- EPHA3 | c.1363_1364del p.L455Vfs*6 | Frame Shift Del (DEL) | VAF 78/184 reads (42%) | called by mutect2, pindel, varscan2
- FAM86B2 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 192/275 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by mutect2, varscan2
- FAT2 | c.4048G>C p.D1350H | Missense Mutation (SNP) | VAF 49/630 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- GNPTAB | c.2540C>A p.T847K | Missense Mutation (SNP) | VAF 27/303 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- GNS | c.368G>T p.W123L | Missense Mutation (SNP) | VAF 248/755 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GRID2IP | c.3577G>T p.D1193Y | Missense Mutation (SNP) | VAF 176/281 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- HTR3D | c.879+8C>G | Splice Region (SNP) | VAF 137/249 reads (55%) | called by muse, mutect2, varscan2
- ITGB1 | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1549 | c.2869A>G p.I957V | Missense Mutation (SNP) | VAF 190/546 reads (35%) | SIFT tolerated (0.97); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MANBA | c.2005C>T p.Q669* (on ENST00000642252; = p.Q623* on NM_005908.4) | Nonsense Mutation (SNP) | VAF 83/203 reads (41%) | called by muse, mutect2, varscan2
- MCC | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 124/245 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MITF | c.879G>C p.E293D (on ENST00000448226 / NM_006722.3; = p.E193D on NM_000248.4) | Missense Mutation (SNP) | VAF 22/504 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.023); called by muse, mutect2
- NLGN4X | c.1244C>G p.T415S | Missense Mutation (SNP) | VAF 274/702 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- PHLDB1 | c.970A>C p.S324R | Missense Mutation (SNP) | VAF 137/332 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- PHLDB1 | c.971G>T p.S324I | Missense Mutation (SNP) | VAF 140/335 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- PNLIP | c.1030C>G p.L344V | Missense Mutation (SNP) | VAF 106/220 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POT1 | c.121A>T p.T41S | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PTPRD | c.707C>G p.P236R | Missense Mutation (SNP) | VAF 86/166 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- RAC2 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 207/576 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RAD51AP2 | c.2462T>A p.L821Q | Missense Mutation (SNP) | VAF 117/187 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- RIF1 | c.4218G>T p.Q1406H | Missense Mutation (SNP) | VAF 30/576 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.22); called by muse, mutect2
- RNF139 | c.812A>G p.D271G | Missense Mutation (SNP) | VAF 391/439 reads (89%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SACS | c.13287_13288del p.Q4430Kfs*34 | Frame Shift Del (DEL) | VAF 36/104 reads (35%) | called by pindel, varscan2
- SLC12A2 | c.243C>G p.F81L | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SLC25A37 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 29/231 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- SUDS3 | c.213-1G>A p.X71_splice | Splice Site (SNP) | VAF 105/326 reads (32%) | called by muse, mutect2, varscan2
- TBX15 | c.1657G>A p.G553R (on ENST00000369429 / NM_001330677.2; = p.G447R on NM_152380.3) | Missense Mutation (SNP) | VAF 39/385 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- TENM2 | c.5227G>T p.D1743Y (on ENST00000518659 / NM_001122679.2; = p.D1504Y on NM_001080428.3) | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.971); called by muse, mutect2
- UGT2A3 | c.461G>A p.C154Y | Missense Mutation (SNP) | VAF 69/120 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- VAPB | c.696T>A p.F232L | Missense Mutation (SNP) | VAF 262/1056 reads (25%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- VPS13B | c.2104C>T p.H702Y | Missense Mutation (SNP) | VAF 19/330 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- WAPL | c.2701G>T p.A901S | Missense Mutation (SNP) | VAF 86/177 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- WNK4 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 225/857 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ZDHHC15 | c.193T>C p.F65L | Missense Mutation (SNP) | VAF 209/210 reads (100%) | SIFT tolerated (0.27); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ZNF780B | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 122/251 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- ZNF891 | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 91/263 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- ADARB2 | c.1569C>A p.I523= | Silent (SNP) | VAF 222/474 reads (47%) | catalogued as rs780275876, COSV67232478; called by muse, mutect2, varscan2
- AL031777.2 | c.267C>T p.R89= | Silent (SNP) | VAF 148/376 reads (39%) | catalogued as rs1223145998; called by muse, mutect2, varscan2
- ARHGEF7 | c.99G>A p.A33= | Silent (SNP) | VAF 53/169 reads (31%) | called by muse, mutect2, varscan2
- BRSK1 | c.525C>T p.F175= | Silent (SNP) | VAF 61/130 reads (47%) | catalogued as rs1222040925, COSV58668022; called by muse, mutect2, varscan2
- CEP89 | c.1137G>A p.E379= | Silent (SNP) | VAF 94/254 reads (37%) | catalogued as COSV59866322; called by muse, mutect2, varscan2
- COL4A2 | c.4047G>A p.R1349= | Silent (SNP) | VAF 65/110 reads (59%) | called by muse, mutect2, varscan2
- CTAGE9 | c.2103C>T p.I701= | Silent (SNP) | VAF 58/555 reads (10%) | called by muse, mutect2, varscan2
- CXorf66 | c.183T>C p.F61= | Silent (SNP) | VAF 56/56 reads (100%) | called by muse, mutect2, varscan2
- DLK1 | c.981C>T p.L327= | Silent (SNP) | VAF 12/303 reads (4%) | catalogued as rs1448630464; called by muse, mutect2
- DNAI1 | c.537T>A p.T179= | Silent (SNP) | VAF 225/478 reads (47%) | called by muse, mutect2, varscan2
- EIF2S2 | c.951C>T p.G317= | Silent (SNP) | VAF 39/478 reads (8%) | catalogued as COSV66621939; called by muse, mutect2
- FAM184B | c.2268C>T p.A756= | Silent (SNP) | VAF 131/336 reads (39%) | catalogued as rs1462473276; called by muse, mutect2, varscan2
- FCRL3 | c.768G>A p.G256= | Silent (SNP) | VAF 48/94 reads (51%) | called by muse, mutect2, varscan2
- ITIH1 | c.1377C>T p.Y459= | Silent (SNP) | VAF 97/206 reads (47%) | catalogued as rs145303032; called by muse, mutect2, varscan2
- KCNS2 | c.102G>A p.T34= | Silent (SNP) | VAF 583/671 reads (87%) | catalogued as COSV54637628, COSV54639004; called by muse, mutect2, varscan2
- KLHL36 | c.672C>T p.R224= | Silent (SNP) | VAF 442/708 reads (62%) | catalogued as rs745918761; called by muse, mutect2, varscan2
- LINGO1 | c.1131C>A p.L377= | Silent (SNP) | VAF 44/488 reads (9%) | called by muse, mutect2
- LVRN | c.291C>T p.R97= | Silent (SNP) | VAF 207/447 reads (46%) | catalogued as COSV100773356, COSV100773438; called by mutect2, varscan2
- MED13L | c.171G>T p.L57= | Silent (SNP) | VAF 363/1037 reads (35%) | called by muse, mutect2, varscan2
- MYOC | c.1278C>T p.V426= | Silent (SNP) | VAF 625/1327 reads (47%) | catalogued as rs1183498744; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBEA | c.7407T>A p.P2469= | Silent (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- NFU1 | c.408T>C p.D136= (on ENST00000410022 / NM_001002755.4; = p.D112= on NM_015700.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/412 reads (6%) | called by muse, mutect2
- NLRP14 | c.2271G>A p.E757= | Silent (SNP) | VAF 17/395 reads (4%) | called by muse, mutect2
- OSBPL3 | c.1140G>A p.L380= | Silent (SNP) | VAF 25/276 reads (9%) | called by muse, mutect2
- OTUD7A | c.1833C>T p.G611= (on ENST00000307050 / NM_001382637.1; = p.G604= on NM_130901.3) | Silent (SNP) | VAF 188/403 reads (47%) | catalogued as rs760442966; called by muse, mutect2, varscan2
- PANX1 | c.774C>T p.T258= | Silent (SNP) | VAF 113/311 reads (36%) | catalogued as rs775393300; called by muse, mutect2, varscan2
- PBOV1 | c.102G>A p.R34= | Silent (SNP) | VAF 120/305 reads (39%) | called by muse, mutect2, varscan2
- PCDHGB6 | c.1524C>T p.S508= | Silent (SNP) | VAF 309/642 reads (48%) | called by muse, mutect2, varscan2
- PCNX2 | c.4629G>A p.T1543= | Silent (SNP) | VAF 121/258 reads (47%) | catalogued as rs757432332, COSV50780709; called by muse, mutect2, varscan2
- PDE2A | c.2151G>A p.A717= | Silent (SNP) | VAF 30/450 reads (7%) | catalogued as rs146881776; called by muse, mutect2
- PGAP4 | c.822C>T p.P274= | Silent (SNP) | VAF 185/376 reads (49%) | called by muse, mutect2, varscan2
- POLD2 | c.696G>A p.Q232= | Silent (SNP) | VAF 328/1018 reads (32%) | called by muse, mutect2, varscan2
- PRKDC | c.870C>T p.Y290= | Silent (SNP) | VAF 81/330 reads (25%) | catalogued as rs376740223; called by muse, mutect2, varscan2
- PRR23C | c.192C>T p.D64= | Silent (SNP) | VAF 107/251 reads (43%) | catalogued as rs750832767; called by muse, mutect2, varscan2
- PSPH | c.321A>T p.L107= | Silent (SNP) | VAF 193/580 reads (33%) | called by muse, mutect2, varscan2
- RNF145 | c.42C>T p.A14= (on ENST00000424310 / NM_001199383.2; = p.A42= on NM_144726.2) | Silent (SNP) | VAF 18/601 reads (3%) | called by muse, mutect2
- SPACA1 | c.87G>A p.G29= | Silent (SNP) | VAF 41/528 reads (8%) | catalogued as rs376457887; called by muse, mutect2
- TDRD12 | c.651C>T p.N217= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs745807381; called by muse, mutect2, varscan2
- TENM3 | c.1668C>T p.N556= | Silent (SNP) | VAF 182/380 reads (48%) | catalogued as rs372557342, COSV69300737; called by muse, mutect2, varscan2
- THSD1 | c.2154C>A p.T718= | Silent (SNP) | VAF 139/317 reads (44%) | called by muse, mutect2, varscan2
- ZKSCAN1 | c.549G>A p.S183= | Silent (SNP) | VAF 288/462 reads (62%) | catalogued as rs762080657; called by muse, varscan2
- ZNF625 | c.538A>C p.R180= | Silent (SNP) | VAF 103/208 reads (50%) | called by muse, mutect2, varscan2
- ZNF835 | c.252C>T p.S84= | Silent (SNP) | VAF 454/963 reads (47%) | catalogued as COSV73379545, COSV73379660; called by muse, mutect2, varscan2
- ZP4 | c.627C>T p.L209= | Silent (SNP) | VAF 279/595 reads (47%) | called by muse, mutect2, varscan2
- ABCA2 | c.*13G>C | 3'UTR (SNP) | VAF 263/580 reads (45%) | called by muse, mutect2, varscan2
- AC245748.1 | c.16-26576C>T | Intron (SNP) | VAF 131/324 reads (40%) | catalogued as rs1212711888, COSV73336506; called by muse, mutect2, varscan2
- CACNA1B | c.530+9150C>T | Intron (SNP) | VAF 59/135 reads (44%) | called by muse, mutect2, varscan2
- FLI1 | c.-85G>A | 5'UTR (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- FOXE1 | c.*7G>A | 3'UTR (SNP) | VAF 398/808 reads (49%) | called by muse, mutect2, varscan2
- HEXD | c.982+237G>A | Intron (SNP) | VAF 63/221 reads (29%) | called by muse, mutect2, varscan2
- ITGB2 | c.1950-50C>T | Intron (SNP) | VAF 90/179 reads (50%) | catalogued as rs758107469; called by muse, mutect2, varscan2
- NDUFV3 | c.170-4782C>T | Intron (SNP) | VAF 244/518 reads (47%) | catalogued as rs767417344; called by muse, mutect2, varscan2
- PIGK | c.987-7016C>G | Intron (SNP) | VAF 308/493 reads (62%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-2008C>T | Intron (SNP) | VAF 90/331 reads (27%) | catalogued as rs754443237, COSV57629751; called by muse, mutect2, varscan2
- REXO1L1P | n.1468C>T | RNA (SNP) | VAF 800/4265 reads (19%) | catalogued as rs771837707; called by muse, mutect2, varscan2
- SETD5 | c.178-174G>T | Intron (SNP) | VAF 83/300 reads (28%) | called by muse, mutect2, varscan2
